Surgical pathology report (de-identified scan), TCGA case TCGA-85-7697, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-7697-01A (Primary Tumor).

[page 1 of 2]
Case ID	Gross Description	Microscopic Description	Diagnosis Details	Comments	Formatted Path Report
					LUNG TISSUE CHECKLIST Specimen type: Pneumonectomy Tumor site: Lung Tumor size: 4 x 3.5 x 3 cm Histologic type: Squamous cell carcinoma Histologic grade: Well differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: Not specified Lymphatic invasion: Not specified Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 2 of 2]
ID	Laterality	Date of procurement
	Left-upper	

Source: NCI Genomic Data Commons file c5d445e5-8eb9-4ca2-b127-c66b1a3fd718 (TCGA-85-7697.F0531CC6-1691-4C66-8B6C-DD260F7EF1AC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).